Surgical pathology report (de-identified scan), TCGA case TCGA-WB-A81V, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Erasmus MC, specimen TCGA-WB-A81V-01A (Primary Tumor).

Short descriptive translation of the pathology report as provided by the

Date report:

Material received:

Material: left adrenal gland

Macroscopic findings

A 7.5x6.5x4.5 specimen surrounded by a grey-brown capsule and attached fatty tissue (123 g formalin-fixed). Upon lamination a yellow-red surface was revealed with hemorrhage. In the center of the lesion a 5.5 cm cystic part is filled with friable red-brown material.

Microscopy findings:

Histologically at HE-, EvG and PAS-staining normal adrenal tissue with a large scarred pseudocyst can be observed. Attached normal adrenal cortex and large polygonal cells with fine granular inclusions and an eosinophilic cytoplasm. The nuclei are large and have gross chromatin alterations. Mitoses can be observed rarely. More sections reveal solid formations of the tumor with collagen-rich bands and focal necrosis.

Diagnosis:

Regressive, pseudocystic pheochromocytoma

Translated by:

ICD-O-3
Pheochromocytoma NOS 8700/0
Site: Adrenal gland NOS C74.9
9/10/13

ICDPA Discrepancy		✓

Source: NCI Genomic Data Commons file abeba1a1-c5a1-4d75-b698-b45f70d6664b (TCGA-WB-A81V.F259073F-45BF-4D44-966D-A64ACE07DF37.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).